Somatic mutation profile of tumor specimen TCGA-WE-A8ZT-06A (aliquot TCGA-WE-A8ZT-06A-11D-A372-08) from TCGA case TCGA-WE-A8ZT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 25.7 years (9,389 days).
Specimen TCGA-WE-A8ZT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf779b51-677e-4d45-8080-1ec15090afd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8ZT-10A (Blood Derived Normal), aliquot TCGA-WE-A8ZT-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/221baa5b-eac5-4677-9d71-70a15cd0c3d2

The open-access MAF lists 557 somatic variants for this specimen: 363 protein-altering or splice-affecting, 173 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 332, Silent 173, Nonsense Mutation 20, Intron 9, RNA 4, Translation Start Site 4, Splice Region 4, Splice Site 3, 5'UTR 3, 3'UTR 2, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 43/96 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV56683948; called by muse, mutect2, varscan2
- PTEN | c.1026+1G>A p.X342_splice | Splice Site (SNP) | VAF 33/53 reads (62%) | hotspot (GDC flag); catalogued as rs786201041, CS043794, CS110216, COSV64288702, COSV64289135, COSV64293873; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1148G>A p.G383D | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as rs1418815071, COSV99447284; called by muse, mutect2, varscan2
- ABCC3 | c.3559C>T p.P1187S | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99559528; called by muse, mutect2, varscan2
- ABCC3 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99559529; called by muse, mutect2, varscan2
- ABCC9 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV99686536; called by muse, mutect2, varscan2
- ACOT11 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs377101876, COSV100650734; called by muse, mutect2
- ACTN1 | c.2311T>C p.F771L | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV99518266; called by muse, mutect2
- ADAM2 | c.1314T>C p.F438= | Splice Region (SNP) | VAF 49/126 reads (39%) | catalogued as COSV99697698; called by muse, mutect2, varscan2
- ADAM28 | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs201643797; called by muse, mutect2, varscan2
- ADAM7 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51535001; called by muse, mutect2, varscan2
- ADAMTS10 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs1555741462, COSV54353252; called by muse, mutect2, varscan2
- ADCK1 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1008647448, COSV99452300; called by muse, mutect2, varscan2
- ADCY8 | c.3019T>G p.C1007G | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99653525; called by muse, mutect2, varscan2
- ADGRB3 | c.1150G>C p.G384R | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV101001493; called by muse, mutect2, varscan2
- ADGRE5 | c.1172C>T p.A391V (on ENST00000242786 / NM_078481.4; = p.A298V on NM_001784.5) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs769484947, COSV54408401; called by muse, mutect2
- ADGRG4 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV54950305; called by muse, mutect2, varscan2
- ADGRG4 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1193295917, COSV99796241; called by muse, mutect2, varscan2
- ADGRV1 | c.10544G>A p.G3515E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs750547850, COSV101316277; called by muse, varscan2
- ADH6 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1274691731, COSV52955220; called by muse, mutect2, varscan2
- AHCTF1 | c.3754C>T p.P1252S (on ENST00000366508; = p.P1226S on NM_015446.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100404165; called by muse, mutect2, varscan2
- AHNAK | c.8461C>T p.P2821S | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.225); catalogued as rs868617744, COSV99948799; called by muse, mutect2, varscan2
- AL121899.2 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.044); catalogued as rs149044769; called by muse, mutect2, varscan2
- ALOX15 | c.1703C>T p.T568I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV99541624; called by muse, mutect2, varscan2
- ALS2CL | c.1909C>T p.Q637* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as COSV100015234; called by muse, mutect2, varscan2
- AMELX | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100498773; called by muse, mutect2, varscan2
- ANAPC1 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV100594965, COSV100595072; called by muse, mutect2, varscan2
- AOX1 | c.828A>T p.K276N | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs1312571666, COSV101022041, COSV65983575; called by muse, mutect2, varscan2
- APOA4 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63360059; called by muse, mutect2, varscan2
- AQP10 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as rs1224372313, COSV100270378; called by muse, mutect2, varscan2
- AREG | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV99144397; called by muse, mutect2, varscan2
- ARHGAP33 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99139327; called by muse, mutect2, varscan2
- ARHGAP36 | c.218C>G p.A73G | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.956); catalogued as COSV99358021; called by muse, mutect2, varscan2
- ARMC4 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs777609514, COSV100537187; called by muse, mutect2, varscan2
- ARMCX5 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55766047, COSV99863476; called by muse, mutect2, varscan2
- ASF1B | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755215195, COSV54616706, COSV99654354, COSV99654358; called by muse, mutect2, varscan2
- ATG2B | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV100738154, COSV100738233; called by muse, mutect2, varscan2
- ATP11C | c.3299G>A p.R1100K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100558364; called by muse, mutect2, varscan2
- ATP1B1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1173910472, COSV100891630; called by muse, mutect2, varscan2
- AURKC | c.907C>T p.P303S (on ENST00000302804 / NM_001015878.2; = p.P269S on NM_003160.3) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.131); catalogued as COSV100248936; called by muse, mutect2, varscan2
- B4GALNT2 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100302686; called by muse, mutect2, varscan2
- BCL11A | c.509G>A p.G170E (on ENST00000335712 / NM_001365609.1; = p.G204E on NM_018014.4) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100186190; called by muse, mutect2, varscan2
- BCL11A | c.508G>A p.G170R (on ENST00000335712 / NM_001365609.1; = p.G204R on NM_018014.4) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779207367, COSV59624354; called by muse, mutect2, varscan2
- BCOR | c.4884T>G p.D1628E (on ENST00000378444 / NM_001123385.2; = p.D1594E on NM_017745.6) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100653707; called by muse, mutect2, varscan2
- BCR | c.1966G>C p.V656L | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100006850; called by muse, mutect2, varscan2
- BRINP3 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0.133); catalogued as rs868419905, COSV100819180, COSV66526336; called by muse, mutect2, varscan2
- CACNA1E | c.1388G>A p.R463K | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100704361, COSV62388640; called by muse, mutect2, varscan2
- CACNA1S | c.5195C>G p.P1732R | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100755219; called by muse, mutect2, varscan2
- CCDC113 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs763584066, COSV99541136; called by muse, mutect2, varscan2
- CD109 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as rs1457242276, COSV54656986; called by muse, mutect2, varscan2
- CD163L1 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100550477; called by muse, mutect2, varscan2
- CD207 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1553400452, COSV101338581; called by mutect2, varscan2
- CDH2 | c.1489T>C p.F497L | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99297863; called by muse, mutect2, varscan2
- CDH20 | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774840430, COSV99406148; called by muse, mutect2, varscan2
- CDH8 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 49/108 reads (45%) | catalogued as rs267604590, COSV100182320, COSV54846997; called by muse, mutect2, varscan2
- CDH9 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99150688; called by muse, mutect2, varscan2
- CEMIP2 | c.2420G>A p.G807E | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1402961118, COSV100987138; called by muse, mutect2, varscan2
- CENPF | c.8830G>A p.G2944R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV100871848; called by muse, mutect2, varscan2
- CFAP58 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 71/104 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs777981562, COSV63832819; called by muse, mutect2, varscan2
- CFAP61 | c.2662G>A p.D888N | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99846010; called by muse, mutect2, varscan2
- CHRDL1 | c.26C>T p.S9L (on ENST00000372045; = p.S15L on NM_145234.4) | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as rs201535850, COSV54326499; called by muse, mutect2, varscan2
- CKMT2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753520086, COSV99562446; called by muse, mutect2
- CLEC4D | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100223107; called by muse, mutect2, varscan2
- CLSPN | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV99231317; called by muse, mutect2, varscan2
- CMTM2 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779636662, COSV99216548; called by muse, mutect2, varscan2
- CNTN1 | c.2898C>G p.I966M | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100751748; called by muse, mutect2, varscan2
- CNTN1 | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100751384; called by muse, mutect2, varscan2
- COL11A1 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1373294721, COSV100617734; called by muse, mutect2, varscan2
- COL2A1 | c.2110C>T p.P704S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100476142, COSV100477117; called by muse, mutect2, varscan2
- COL4A2 | c.3109G>A p.G1037R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100847433; called by muse, mutect2, varscan2
- COL5A1 | c.2953G>A p.G985S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65664725, COSV65666338; called by muse, mutect2, varscan2
- COL6A6 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as rs747310047, COSV100650672; called by muse, mutect2, varscan2
- CORO2A | c.1443T>G p.N481K | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV100674061, COSV59662529; called by muse, mutect2, varscan2
- CPB2 | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99473228; called by muse, mutect2, varscan2
- CPNE8 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012840269, COSV100504895, COSV100505268; called by muse, mutect2, varscan2
- CPO | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as rs771644753, COSV55939003; called by muse, mutect2, varscan2
- CRISP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs267601066, COSV100237025; called by muse, mutect2, varscan2
- CRLF3 | c.1285G>T p.G429* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100158485; called by muse, mutect2, varscan2
- CSE1L | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.7); PolyPhen benign (0.033); catalogued as COSV99522157; called by muse, mutect2, varscan2
- CSF2RB | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs373244465, COSV99454244; called by muse, mutect2, varscan2
- CSMD1 | c.3640G>A p.D1214N (on ENST00000520002; = p.D1213N on NM_033225.6) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100146636, COSV59373696; called by muse, mutect2, varscan2
- CSMD3 | c.5159G>A p.G1720E (on ENST00000297405 / NM_001363185.1; = p.G1616E on NM_052900.3) | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52358480, COSV99842586; called by muse, mutect2, varscan2
- CSMD3 | c.2047C>T p.R683C (on ENST00000297405 / NM_001363185.1; = p.R579C on NM_052900.3) | Missense Mutation (SNP) | VAF 123/241 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1266203286, COSV52185681; called by muse, mutect2, varscan2
- CTTNBP2 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.059); catalogued as COSV99354536; called by muse, mutect2, varscan2
- CYTH3 | c.1181G>A p.R394Q (on ENST00000396741; = p.R393Q on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 149/358 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs780996917, COSV60364287; called by muse, mutect2, varscan2
- DCC | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as COSV100501992; called by muse, mutect2, varscan2
- DCC | c.3445C>T p.R1149* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs1192643454, COSV71431283; called by muse, mutect2, varscan2
- DDN | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1224152908, COSV100305327; called by muse, mutect2, varscan2
- DIAPH1 | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99527019; called by muse, mutect2, varscan2
- DIAPH1 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.349); catalogued as COSV99527020; called by muse, mutect2, varscan2
- DNAH17 | c.10438G>T p.E3480* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as rs768288144, COSV101103055; called by muse, mutect2, varscan2
- DNAJC5B | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as rs1217304685, COSV52539978; called by muse, mutect2, varscan2
- DNASE1L3 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as rs867139693, COSV100568791, COSV59155950; called by muse, mutect2, varscan2
- DRAXIN | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs147056259; called by muse, mutect2, varscan2
- DYRK4 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99157338; called by muse, mutect2, varscan2
- E2F8 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100001647; called by muse, mutect2, varscan2
- EDIL3 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.574); catalogued as COSV99678334; called by muse, mutect2, varscan2
- EDNRA | c.1054T>C p.Y352H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs1247822547, COSV100163552; called by muse, mutect2, varscan2
- ELAVL4 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100836845; called by muse, mutect2, varscan2
- EP300 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as COSV99609417; called by muse, mutect2, varscan2
- EP400 | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100201882; called by muse, mutect2, varscan2
- EP400 | c.3692C>T p.P1231L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100201887; called by mutect2, varscan2
- EPB41L1 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99151319; called by muse, mutect2, varscan2
- F13A1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99343638; called by muse, mutect2, varscan2
- FAM209A | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV99711634; called by muse, mutect2, varscan2
- FAM47C | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV63726817; called by muse, mutect2, varscan2
- FAM83B | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV60919361; called by muse, mutect2, varscan2
- FANCD2 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV99812008; called by muse, mutect2, varscan2
- FAT1 | c.13670C>T p.S4557F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101499333, COSV101499527; called by muse, mutect2, varscan2
- FBXO43 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV71055804; called by muse, mutect2, varscan2
- FCN2 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.506); catalogued as COSV99391391; called by muse, mutect2, varscan2
- FCN2 | c.429C>T p.T143= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as rs532739715, COSV99391392; called by muse, varscan2
- FCRL5 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.039); catalogued as COSV62511760; called by muse, mutect2, varscan2
- FLNB | c.3211G>A p.G1071R | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99914142; called by muse, mutect2, varscan2
- FMO2 | c.1109G>C p.G370A | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99269272; called by muse, mutect2, varscan2
- FOXI1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100089508, COSV60389917; called by muse, varscan2
- FRG2B | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs570249949, COSV71042741; called by muse, mutect2
- FSTL5 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.142); catalogued as rs182769441, COSV100059184; called by muse, mutect2, varscan2
- GAL3ST1 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as rs777916848, COSV100143186; called by muse, mutect2, varscan2
- GAREM1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757787792, COSV99331132; called by muse, mutect2, varscan2
- GCLM | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV100934015; called by muse, mutect2, varscan2
- GCLM | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs780522121, COSV100934016; called by muse, mutect2, varscan2
- GCNA | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs759448717, COSV101032624; called by mutect2, varscan2
- GHR | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100051597; called by muse, mutect2, varscan2
- GJA4 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100654718; called by muse, mutect2, varscan2
- GLRA4 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV101009683; called by muse, mutect2, varscan2
- GLT6D1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs370612547, COSV100874571; called by muse, mutect2, varscan2
- GML | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV55278268, COSV55278556; called by muse, mutect2, varscan2
- GPBP1 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as COSV53313444, COSV99303001; called by muse, mutect2, varscan2
- GPC4 | c.390T>A p.H130Q | Missense Mutation (SNP) | VAF 198/512 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100895564, COSV63698499; called by muse, mutect2, varscan2
- GPC5 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65599455; called by muse, mutect2, varscan2
- GPR101 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs761526487, COSV53240593; called by muse, mutect2, varscan2
- GPR12 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV101198008; called by muse, mutect2, varscan2
- GPRC6A | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100114618; called by muse, mutect2, varscan2
- GRID1 | c.1185A>T p.E395D | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100025583; called by muse, mutect2, varscan2
- GRID2 | c.760T>G p.F254V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.966); catalogued as COSV99944491; called by muse, mutect2, varscan2
- GRIK3 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV66146682; called by muse, mutect2, varscan2
- GRIN2A | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV58043072; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2146A>T p.K716* (on ENST00000265755 / NM_016328.3; = p.K701* on NM_005685.4) | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99735136; called by muse, mutect2, varscan2
- GTPBP3 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1456650207, COSV100259022; called by muse, mutect2, varscan2
- HAUS8 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs747503889, COSV53727194, COSV99505429; called by muse, mutect2, varscan2
- HBB | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs33929415, CD076806, CD084149, CM099828, CM920971, CM984070, COSV100092837; ClinVar: benign; called by muse, mutect2, varscan2
- HEG1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100230803; called by muse, mutect2, varscan2
- IDO1 | c.402G>A p.W134* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV53713117; called by muse, mutect2, varscan2
- IFNG | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.149); catalogued as COSV99971235; called by muse, mutect2, varscan2
- IFT57 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99197943; called by muse, mutect2, varscan2
- IGF2R | c.1209C>T p.L403= | Splice Region (SNP) | VAF 26/59 reads (44%) | catalogued as COSV63626500; called by muse, mutect2, varscan2
- IGHMBP2 | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99662386; called by muse, mutect2, varscan2
- IGSF1 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100812207; called by muse, mutect2, varscan2
- IL2RB | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV99345085; called by muse, mutect2
- INSIG1 | c.386T>G p.V129G | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100453057; called by muse, mutect2, varscan2
- IQSEC3 | c.2896G>A p.E966K (on ENST00000538872 / NM_001170738.2; = p.E663K on NM_015232.1) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58285191; called by muse, mutect2, varscan2
- ITGA10 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.688); catalogued as rs1243925918, COSV100994987; called by muse, mutect2, varscan2
- ITGA7 | c.3128G>A p.R1043Q (on ENST00000555728; = p.R999Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs372579814, COSV99149897; called by muse, mutect2, varscan2
- ITGB8 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245360765, COSV99752007; called by muse, mutect2, varscan2
- JAKMIP2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV99508882; called by muse, mutect2, varscan2
- JAKMIP3 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.374); catalogued as rs773850884, COSV100059648, COSV100060050; called by muse, mutect2, varscan2
- JCAD | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100948513; called by muse, mutect2, varscan2
- KATNA1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193519113, COSV100167927; called by muse, mutect2, varscan2
- KCNA4 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 70/157 reads (45%) | catalogued as COSV60256279; called by muse, mutect2, varscan2
- KCNAB1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs1481068176, COSV67490794; called by muse, mutect2, varscan2
- KCNH2 | c.307+1G>A p.X103_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as rs1249570722, COSV100060670; called by muse, mutect2, varscan2
- KCNQ3 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1172039592, COSV101196291; called by muse, mutect2, varscan2
- KDM4B | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50270755; called by muse, mutect2, varscan2
- KDM4B | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99346989; called by muse, mutect2, varscan2
- KIRREL2 | c.1610G>A p.S537N | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1223754455, COSV99384249; called by muse, mutect2, varscan2
- KLB | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV99962380; called by muse, mutect2, varscan2
- KLHL38 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.093); catalogued as COSV100384513; called by muse, mutect2, varscan2
- LAMA3 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV100557374; called by muse, mutect2, varscan2
- LARP1B | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as rs1184794038, COSV99218679; called by muse, mutect2, varscan2
- LILRB2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV100079538; called by muse, mutect2, varscan2
- LINS1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100130406; called by muse, mutect2, varscan2
- LRP1B | c.13705G>T p.G4569W | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157317785, COSV101255665; called by muse, mutect2, varscan2
- LRRC74A | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV53609084, COSV99372614; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.932); catalogued as COSV101012217; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV101012219; called by muse, mutect2, varscan2
- MACC1 | c.830T>C p.L277S | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs555877682, COSV100256096; called by muse, mutect2, varscan2
- MAEL | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs768269478, COSV63304489; called by muse, mutect2, varscan2
- MAGEC2 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.03); catalogued as COSV99909791; called by muse, mutect2, varscan2
- MARCO | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100503687; called by muse, mutect2
- MATN2 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99646788; called by muse, mutect2
- MC3R | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs369456606, COSV54764996; called by muse, mutect2, varscan2
- MCF2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1267860187, COSV100644973, COSV58480427; called by muse, mutect2, varscan2
- MEAF6 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV99952807; called by muse, mutect2, varscan2
- MICAL1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs540868259, COSV100668674; called by muse, mutect2, varscan2
- MME | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.063); catalogued as COSV100852487, COSV64709353, COSV64709653; called by muse, mutect2, varscan2
- MMRN1 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99307501; called by muse, mutect2, varscan2
- MORC1 | c.2950A>T p.N984Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as COSV99227178; called by muse, mutect2, varscan2
- MPP6 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1272691735, COSV99757745; called by muse, mutect2, varscan2
- MRC1 | c.2771G>A p.R924Q | Missense Mutation (SNP) | VAF 190/482 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99519451; called by muse, mutect2, varscan2
- MROH5 | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.784); catalogued as rs779470251, COSV101436085; called by muse, mutect2
- MROH9 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs762044130, COSV100882912; called by muse, mutect2, varscan2
- MRTFB | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.12); catalogued as COSV100371610; called by muse, varscan2
- MTDH | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs929674164, COSV100292718; called by muse, mutect2, varscan2
- MTTP | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs1468725368, COSV99645447; called by muse, mutect2, varscan2
- MUC16 | c.40625G>A p.G13542E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs78879019; called by muse, mutect2, varscan2
- MUC16 | c.40624G>A p.G13542R | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); catalogued as rs755391254, COSV66692175; called by muse, mutect2, varscan2
- MXRA5 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV99478394; called by muse, mutect2, varscan2
- MYBPHL | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs112174652; called by muse, mutect2, varscan2
- MYO7B | c.5983G>A p.V1995M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100264869; called by muse, mutect2, varscan2
- MYOF | c.5272G>A p.G1758R | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100826027; called by muse, mutect2, varscan2
- NCKAP1L | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs867120923, COSV99515487; called by muse, mutect2, varscan2
- NCKIPSD | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV99584124; called by muse, mutect2, varscan2
- NCOA7 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99997221, COSV99997459; called by muse, mutect2, varscan2
- NDNF | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV101113162; called by muse, mutect2, varscan2
- NELL2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.13); catalogued as COSV100418415, COSV61581141; called by muse, mutect2, varscan2
- NEXMIF | c.3799C>T p.P1267S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as COSV99281413; called by muse, mutect2, varscan2
- NEXMIF | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as COSV50145813; called by muse, mutect2, varscan2
- NLRP11 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV64085665; called by muse, mutect2, varscan2
- NLRP7 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100053110; called by muse, mutect2, varscan2
- NMRAL1 | c.720G>A p.K240= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as rs1567345232; called by muse, mutect2, varscan2
- NTN4 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750508188, COSV100643836, COSV100643866; called by muse, mutect2
- NUAK1 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs757960457, COSV54601002; called by muse, mutect2, varscan2
- OCEL1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1279461335, COSV99285786; called by muse, mutect2, varscan2
- OCEL1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1306960408, COSV99285788; called by muse, mutect2, varscan2
- OFD1 | c.1538A>G p.D513G | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100407051; called by muse, mutect2, varscan2
- OGFRL1 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745704310, COSV100965793; called by muse, mutect2, varscan2
- OR10H2 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100008844; called by muse, mutect2, varscan2
- OR10K1 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.998); catalogued as COSV99193819; called by muse, mutect2, varscan2
- OR13G1 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV100687471; called by muse, mutect2, varscan2
- OR2L3 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63454966, COSV63455084; called by muse, mutect2, varscan2
- OR2T34 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.029); catalogued as rs775675620, COSV100170466; called by muse, mutect2, varscan2
- OR2T5 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV100822179, COSV100822212; called by mutect2, varscan2
- OR4A15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/88 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs149233751, COSV59033784, COSV59035376; called by muse, mutect2, varscan2
- OR4D5 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs142766960, COSV58305795; called by muse, mutect2, varscan2
- OR4P4 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV100111800; called by muse, mutect2, varscan2
- OR4S2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56746238; called by muse, mutect2, varscan2
- OR51E1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101211532, COSV67810131; called by muse, mutect2, varscan2
- OR52A1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61092733; called by muse, mutect2, varscan2
- OR52B4 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV68769197; called by muse, mutect2, varscan2
- OR52E6 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV61433523; called by muse, mutect2, varscan2
- OR6C68 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV65563120, COSV65564181; called by muse, mutect2, varscan2
- OR7C2 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99934595; called by muse, mutect2, varscan2
- OR8B2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); catalogued as COSV100899460; called by muse, mutect2, varscan2
- P3H2 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100078136; called by muse, mutect2, varscan2
- PADI4 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100966885; called by muse, mutect2, varscan2
- PCDH1 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376280886, COSV99746683; called by muse, mutect2, varscan2
- PCDHA1 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1332112190, COSV100974416; called by muse, mutect2, varscan2
- PCDHA9 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65327070; called by muse, mutect2, varscan2
- PCDHB13 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.443); catalogued as rs782331919, COSV53402802; called by muse, mutect2, varscan2
- PCDHB6 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV50692739, COSV99170033; called by muse, mutect2, varscan2
- PCDHGA4 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99543315; called by muse, mutect2, varscan2
- PCDHGA4 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1157643001, COSV99543317; called by muse, mutect2, varscan2
- PCDHGA8 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as rs1267376494, COSV99543320; called by muse, mutect2, varscan2
- PDS5B | c.4252C>T p.P1418S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.986); catalogued as rs1291998716, COSV100221311, COSV59726328; called by muse, mutect2, varscan2
- PEX5L | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV99829486; called by muse, varscan2
- PGGHG | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101164375; called by muse, mutect2
- PHF24 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV99646204; called by muse, mutect2, varscan2
- PKHD1L1 | c.7277G>A p.G2426E | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs752180205, COSV65743489; called by muse, mutect2, varscan2
- PLCB4 | c.2963G>A p.G988E | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV53802446, COSV99595102; called by muse, mutect2, varscan2
- PLEKHA8 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV99322014; called by muse, mutect2, varscan2
- PNLDC1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as rs1400653141, COSV99277711; called by muse, mutect2
- PNLDC1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs781459190, COSV99277715, COSV99278042; called by muse, mutect2
- POF1B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as rs755146274, COSV99427157; called by muse, mutect2, varscan2
- POLR3A | c.3160C>A p.H1054N | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100965766; called by muse, mutect2, varscan2
- PPP1R12A | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs766758074, COSV99700641; called by muse, mutect2, varscan2
- PPP1R3A | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52878848, COSV52889729; called by muse, mutect2, varscan2
- PPP1R3A | c.2499C>G p.D833E | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV99034384, COSV99493716; called by muse, mutect2, varscan2
- PRICKLE1 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs1156455994, COSV100454091; called by muse, mutect2, varscan2
- PRKG1 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100907400; called by muse, mutect2, varscan2
- PRMT5 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV53546529, COSV99363106; called by muse, mutect2
- PRORP | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV99156141; called by muse, mutect2, varscan2
- PROSER1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs375394939; called by muse, mutect2, varscan2
- PRRG3 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV64850928; called by muse, mutect2, varscan2
- PRSS58 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV73488664; called by muse, mutect2, varscan2
- PTPRD | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61929760, COSV61929969; called by muse, mutect2, varscan2
- RAB3IP | c.800C>T p.P267L (on ENST00000550536 / NM_175623.4; = p.P251L on NM_022456.5) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99923479; called by muse, mutect2, varscan2
- RALGAPA2 | c.4250C>T p.S1417F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1228545924, COSV99174458; called by muse, mutect2, varscan2
- RFX3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.099); catalogued as COSV100175565, COSV56520130; called by muse, mutect2, varscan2
- RGS7 | c.812G>T p.R271I | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100465677; called by muse, mutect2, varscan2
- RHBDF1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1471984877, COSV99244972; called by muse, mutect2, varscan2
- RIMS3 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65505479; called by muse, mutect2, varscan2
- RNF152 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV100455315; called by muse, mutect2, varscan2
- RNF17 | c.3126G>A p.W1042* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99694013; called by muse, mutect2, varscan2
- RNF31 | c.284G>A p.W95* | Nonsense Mutation (SNP) | VAF 33/89 reads (37%) | catalogued as COSV99396106; called by muse, mutect2, varscan2
- ROBO2 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100168853; called by muse, mutect2, varscan2
- RPS19BP1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs199952941, COSV58180543; called by muse, mutect2, varscan2
- RTL4 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100466066; called by muse, mutect2, varscan2
- RXFP2 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 121/296 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV53635903; called by muse, mutect2, varscan2
- SATB2 | c.1040G>A p.R347K | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs757817590, COSV99612143; called by muse, mutect2, varscan2
- SCARA5 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100108014; called by muse, mutect2, varscan2
- SCN1A | c.2062G>A p.E688K (on ENST00000303395 / NM_001202435.3; = p.E677K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV100321357; called by muse, mutect2, varscan2
- SCN2A | c.5501C>T p.P1834L | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99332793; called by muse, mutect2, varscan2
- SCN3A | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142323631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV101269657; called by muse, mutect2, varscan2
- SENP7 | c.3046C>T p.H1016Y | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100053658; called by muse, varscan2
- SGCE | c.1141G>A p.G381S (on ENST00000647096; = p.G345S on NM_003919.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553677309, COSV99722802; called by muse, mutect2, varscan2
- SHLD2 | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100079246, COSV100079398; called by muse, mutect2, varscan2
- SLC16A10 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375453220, COSV100920941, COSV64355083; called by muse, mutect2, varscan2
- SLC1A6 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV99694027; called by muse, mutect2, varscan2
- SLC22A9 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.703); catalogued as rs1270328866, COSV99655269; called by muse, mutect2, varscan2
- SLC25A24 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99916473; called by muse, mutect2, varscan2
- SLC35D2 | c.419+2T>G p.X140_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99480978; called by muse, mutect2, varscan2
- SLC35G2 | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs752774448, COSV101262077; called by muse, mutect2, varscan2
- SLC4A11 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as rs748184113, COSV66261775; called by muse, mutect2, varscan2
- SLC5A1 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99833639; called by muse, mutect2, varscan2
- SMARCA2 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100571420, COSV61813482; called by muse, mutect2, varscan2
- SMYD1 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.028); catalogued as COSV101352483; called by muse, mutect2, varscan2
- SNAP91 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs868179995, COSV99536132; called by muse, mutect2, varscan2
- SNCAIP | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV99749710; called by muse, mutect2, varscan2
- SPAG17 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60452821; called by muse, mutect2, varscan2
- SPATA18 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99730987; called by muse, mutect2, varscan2
- SPATA19 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100141214; called by muse, mutect2, varscan2
- SPATA31E1 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as rs754891073, COSV100350803; called by muse, mutect2, varscan2
- SPG11 | c.5356G>A p.E1786K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.108); catalogued as COSV99969238; called by muse, mutect2, varscan2
- SPHKAP | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs868289269, COSV100764299; called by muse, mutect2, varscan2
- SPHKAP | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 136/361 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100764300, COSV60891512; called by muse, mutect2, varscan2
- ST18 | c.2395G>A p.G799S | Missense Mutation (SNP) | VAF 90/200 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV99390605; called by muse, mutect2, varscan2
- ST8SIA4 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 30/69 reads (43%) | PolyPhen probably damaging (0.956); catalogued as COSV51506467; called by muse, mutect2, varscan2
- STRA8 | c.967G>C p.E323Q (on ENST00000275764; = p.E301Q on NM_182489.2) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1317444089, COSV99312572; called by muse, mutect2, varscan2
- SUN5 | c.1043A>T p.N348I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758335571, COSV100644872; called by muse, mutect2, varscan2
- TAOK1 | c.1220G>C p.R407T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99914497; called by muse, mutect2, varscan2
- TAOK2 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV54237033; called by muse, mutect2, varscan2
- TECTA | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as rs751352958, COSV50687793; called by muse, mutect2, varscan2
- TEX11 | c.253G>A p.G85R (on ENST00000344304; = p.G70R on NM_031276.3) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.198); catalogued as COSV100722080; called by muse, mutect2, varscan2
- TGM1 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99253164; called by muse, mutect2, varscan2
- THAP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs866807631, COSV54273801, COSV99576736; called by muse, mutect2, varscan2
- THEMIS | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1448509570, COSV100965495; called by muse, mutect2, varscan2
- THOC2 | c.3656C>T p.S1219L | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1414075506, COSV55547899; called by muse, mutect2, varscan2
- THOC2 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99833875; called by muse, mutect2, varscan2
- TIAM1 | c.3622G>A p.D1208N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs765183763, COSV99737669; called by muse, mutect2, varscan2
- TIAM1 | c.1915C>A p.L639I | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV99737671; called by muse, mutect2, varscan2
- TIMM21 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99400168; called by muse, mutect2, varscan2
- TIMM21 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99400170; called by muse, mutect2, varscan2
- TLR9 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100645703; called by muse, mutect2, varscan2
- TMC5 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.335); catalogued as COSV66869783; called by muse, mutect2
- TNFRSF8 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs370973053, COSV55796410; called by muse, mutect2, varscan2
- TPTE2 | c.832C>T p.H278Y (on ENST00000400230 / NM_199254.2; = p.H201Y on NM_130785.3) | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99690712; called by muse, mutect2, varscan2
- TSBP1 | c.1397C>T p.S466F (on ENST00000617061; = p.S471F on NM_006781.5) | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1175717782, COSV100898899, COSV66660357; called by muse, mutect2, varscan2
- TTC21A | c.3910C>T p.P1304S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99827013; called by muse, mutect2, varscan2
- TTN | c.48901G>A p.E16301K (on ENST00000591111; = p.E8877K on NM_003319.4) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | PolyPhen benign (0.033); catalogued as COSV60169071; called by muse, mutect2, varscan2
- TTN | c.11699C>T p.S3900L (on ENST00000591111; = p.S3854L on NM_003319.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100623175; called by muse, mutect2, varscan2
- TUBA8 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV100283168; called by muse, mutect2, varscan2
- UBQLN3 | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100293872; called by muse, mutect2, varscan2
- UBXN8 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1350442687, COSV99668029; called by muse, mutect2
- UGT2B10 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145159685, COSV55323974; called by muse, mutect2, varscan2
- USH2A | c.10768C>T p.P3590S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100239510; called by muse, mutect2, varscan2
- USP29 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as rs1436817694, COSV99572367; called by muse, mutect2, varscan2
- USP44 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV104384627, COSV51567712; called by muse, mutect2, varscan2
- VPS13D | c.2623C>T p.L875F | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV50630980, COSV99167810; called by muse, mutect2, varscan2
- VWC2L | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768752069, COSV100435195, COSV100436165; called by muse, mutect2, varscan2
- WDR72 | c.2657G>A p.R886K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV64747161; called by muse, mutect2, varscan2
- WNT3 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV99843367; called by muse, mutect2, varscan2
- WT1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.053); catalogued as rs1230675954, COSV100188606, COSV60078705; called by muse, mutect2, varscan2
- ZAN | c.6886G>A p.G2296R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV100770029; called by muse, mutect2
- ZBTB5 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100312884; called by muse, mutect2, varscan2
- ZC3H7A | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as COSV100865569, COSV63270665; called by muse, mutect2, varscan2
- ZDHHC9 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV100852278; called by muse, mutect2, varscan2
- ZDHHC9 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1263207152, COSV100852279, COSV64096206; called by muse, mutect2, varscan2
- ZFP36L1 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867766935, COSV100322817; called by muse, mutect2, varscan2
- ZNF10 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs771491576, COSV99940114; called by muse, mutect2, varscan2
- ZNF101 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100543606; called by muse, mutect2, varscan2
- ZNF354A | c.1419A>C p.K473N | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100234586; called by muse, mutect2, varscan2
- ZNF385D | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.554); catalogued as COSV99875786; called by muse, varscan2
- ZNF418 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV101268969; called by muse, mutect2, varscan2
- ZNF516 | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV101487338; called by muse, mutect2, varscan2
- ZNF528 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs548387352, COSV100846705; called by muse, mutect2, varscan2
- ZNF668 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100336799; called by muse, mutect2, varscan2
- ZNF668 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.034); catalogued as COSV100336803; called by muse, mutect2, varscan2
- ZNF780A | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 74/195 reads (38%) | catalogued as rs141772559; called by muse, mutect2, varscan2
- ZNF84 | c.2113C>T p.H705Y | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ACSM3 | c.390C>T p.V130= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs770997675, COSV99184800; called by muse, mutect2, varscan2
- ADAMTS10 | c.2256G>A p.Q752= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV54360401, COSV99547516; called by muse, mutect2, varscan2
- ADAMTS2 | c.951G>A p.R317= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV51071842; called by muse, mutect2, varscan2
- ADH1C | c.279C>T p.L93= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs759673010, COSV101565195; called by muse, mutect2, varscan2
- AK2 | c.183G>T p.R61= (on ENST00000354858; = p.R103= on NM_001625.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs772756276, COSV100710027; called by muse, mutect2, varscan2
- ANO3 | c.2805T>C p.I935= | Silent (SNP) | VAF 61/135 reads (45%) | catalogued as COSV99884572; called by muse, mutect2, varscan2
- APOB | c.2764C>T p.L922= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99028631, COSV99266991; called by muse, mutect2, varscan2
- ARFGEF2 | c.690C>T p.F230= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as rs751892205, COSV64212264; called by muse, mutect2, varscan2
- ARHGEF10 | c.1758C>T p.P586= (on ENST00000398564; = p.P561= on NM_014629.4) | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as rs373443843; called by muse, mutect2, varscan2
- ARMCX5 | c.225G>A p.R75= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV99863474; called by muse, mutect2, varscan2
- ATG2A | c.3033C>T p.F1011= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs376523340; called by muse, mutect2, varscan2
- BPIFB1 | c.549G>A p.Q183= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV99487556; called by muse, mutect2, varscan2
- BRSK2 | c.1767C>T p.F589= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs762641396, COSV100372983; called by muse, mutect2
- C1orf131 | c.687G>A p.K229= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV100009948, COSV59642930; called by muse, mutect2, varscan2
- C5 | c.2877C>T p.F959= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV99798435; called by muse, mutect2, varscan2
- CATSPER3 | c.654C>T p.F218= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV50950695; called by muse, mutect2, varscan2
- CBLN4 | c.486G>A p.T162= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs369524117; called by muse, mutect2, varscan2
- CCDC81 | c.768A>C p.S256= (on ENST00000445632 / NM_001156474.2; = p.S166= on NM_021827.4) | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV99564661; called by muse, mutect2
- CD8A | c.207C>T p.F69= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99374531; called by muse, mutect2, varscan2
- CDH10 | c.2016C>T p.I672= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs201737578, COSV52573402, COSV52582613; called by muse, mutect2, varscan2
- CDH15 | c.90C>T p.T30= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV99228672; called by muse, mutect2, varscan2
- CDK5 | c.21G>A p.L7= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1208925270, COSV99878076; called by muse, mutect2, varscan2
- CHD6 | c.4962C>T p.S1654= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100951262; called by muse, mutect2, varscan2
- CHST5 | c.129C>T p.L43= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100292071; called by muse, mutect2, varscan2
- CKMT2 | c.552G>A p.E184= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as rs144184195; called by muse, mutect2
- CLEC2D | c.141C>T p.I47= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs892148226, COSV99325125; called by muse, mutect2, varscan2
- COL2A1 | c.2109C>T p.F703= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV61528231; called by muse, mutect2, varscan2
- CPED1 | c.2292G>A p.Q764= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV100121245; called by muse, mutect2, varscan2
- CPT2 | c.1002C>T p.D334= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs1417091645, COSV99598271; called by muse, mutect2, varscan2
- CSMD1 | c.591C>T p.F197= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs774873483, COSV101223859, COSV68251749; called by muse, mutect2, varscan2
- CSMD3 | c.600C>T p.I200= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV52160115, COSV52314832; called by muse, mutect2, varscan2
- CTNND2 | c.2814C>T p.V938= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100479549; called by muse, mutect2, varscan2
- CTRC | c.204C>T p.F68= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs773793601, COSV65621345; called by muse, mutect2, varscan2
- CYP1B1 | c.1095G>A p.G365= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99308066; called by muse, mutect2, varscan2
- CYP4A22 | c.342G>A p.P114= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs537019487, COSV99595246; called by muse, mutect2, varscan2
- DNAH17 | c.10437G>A p.S3479= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs773220705, COSV101103057; called by muse, mutect2, varscan2
- DNAH3 | c.687G>A p.S229= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as rs780461804, COSV54530432; called by muse, mutect2, varscan2
- DNAH5 | c.11700C>T p.T3900= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs777190482, COSV99452373; called by muse, mutect2, varscan2
- DNAH9 | c.5997C>T p.D1999= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV99307186; called by muse, mutect2, varscan2
- DNAH9 | c.9177A>G p.R3059= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV99307188; called by muse, mutect2, varscan2
- DRAM1 | c.606G>C p.A202= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV99315738; called by muse, mutect2, varscan2
- DRD1 | c.828G>A p.V276= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV101192507; called by muse, mutect2, varscan2
- DRD5 | c.942C>T p.I314= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV100431957; called by muse, mutect2, varscan2
- DSC1 | c.2466C>T p.F822= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV99938004; called by muse, mutect2, varscan2
- DYNAP | c.270A>G p.R90= (on ENST00000321600; = p.R64= on NM_173629.3) | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as rs1231983938, COSV100391801; called by muse, mutect2, varscan2
- DYNC1H1 | c.3252C>T p.V1084= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs750074486, COSV100795182; called by muse, mutect2, varscan2
- ECI2 | c.627C>T p.P209= (on ENST00000380118 / NM_206836.3; = p.P179= on NM_006117.2) | Silent (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- EMP2 | c.261C>T p.F87= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs1394309250, COSV100852858; called by muse, mutect2, varscan2
- ETF1 | c.393C>T p.F131= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV100860238; called by muse, mutect2, varscan2
- FBXW9 | c.607C>T p.L203= (on ENST00000587955; = p.L213= on NM_032301.3) | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100790391; called by muse, mutect2, varscan2
- FGD5 | c.3375G>A p.G1125= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1314071655, COSV53251832; called by muse, mutect2, varscan2
- FOSB | c.603C>T p.I201= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100798797; called by muse, mutect2
- FYB2 | c.1455C>T p.S485= | Silent (SNP) | VAF 48/150 reads (32%) | catalogued as COSV100599698; called by muse, mutect2, varscan2
- GABRA6 | c.714G>A p.R238= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV50877396; called by muse, mutect2, varscan2
- GALNT12 | c.1602G>A p.Q534= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100899174; called by muse, mutect2, varscan2
- GALNT14 | c.1482G>A p.K494= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100205248; called by muse, mutect2, varscan2
- GALR1 | c.615C>T p.F205= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV55315806, COSV55317357; called by muse, mutect2, varscan2
- GAS2 | c.486G>A p.E162= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs200683264, COSV99535453; called by muse, mutect2, varscan2
- GNAQ | c.1059G>A p.L353= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV99681577; called by muse, mutect2, varscan2
- GPR108 | c.1110C>T p.I370= (on ENST00000264080 / NM_001080452.1; = p.I128= on NM_020171.2) | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as rs775328365, COSV99901470; called by muse, mutect2, varscan2
- GSDMC | c.264C>T p.I88= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV99416312; called by muse, mutect2, varscan2
- GSE1 | c.27G>A p.K9= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV99496999; called by muse, mutect2, varscan2
- HCFC1 | c.1098C>T p.P366= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1557116382, COSV100129617; called by muse, mutect2, varscan2
- HNRNPU | c.1476G>A p.K492= (on ENST00000283179; = p.K554= on NM_004501.3) | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV99310550; called by muse, mutect2, varscan2
- IFI30 | c.234C>T p.F78= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs1299975910, COSV99717622; called by muse, mutect2
- IFIT1B | c.591G>A p.R197= | Silent (SNP) | VAF 143/219 reads (65%) | catalogued as COSV100879100, COSV65663674; called by muse, mutect2, varscan2
- IFRD2 | c.1359C>T p.L453= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100269259, COSV100269722; called by muse, mutect2, varscan2
- IL1F10 | c.123G>A p.K41= | Silent (SNP) | VAF 53/151 reads (35%) | catalogued as rs746995278, COSV100520222; called by muse, mutect2
- INSIG1 | c.387C>T p.V129= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100453058; called by muse, mutect2, varscan2
- IRAK2 | c.267C>T p.I89= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs1169836874, COSV99844231; called by muse, mutect2
- ITGA7 | c.3129G>A p.R1043= (on ENST00000555728; = p.R999= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV99151059; called by muse, mutect2, varscan2
- ITGB5 | c.441C>T p.S147= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as COSV99950961; called by muse, mutect2, varscan2
- JPH2 | c.1137C>T p.I379= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs143158930, COSV100881587; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNA3 | c.1674G>A p.T558= | Silent (SNP) | VAF 49/152 reads (32%) | catalogued as rs1466966510, COSV63902092, COSV63902162; called by muse, mutect2, varscan2
- KCND2 | c.1014C>T p.F338= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs781428853, COSV58580411; called by muse, mutect2, varscan2
- KCNJ3 | c.1074G>A p.V358= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV54541407; called by muse, mutect2, varscan2
- KIAA1841 | c.270C>T p.S90= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV99694063; called by muse, mutect2, varscan2
- KRT38 | c.969G>A p.L323= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV99878314; called by muse, mutect2, varscan2
- KRT76 | c.1440G>A p.V480= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV60119636; called by muse, mutect2, varscan2
- KY | c.1632A>G p.E544= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV101415022; called by muse, varscan2
- LIPI | c.357G>A p.R119= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs866468919, COSV60710335; called by muse, mutect2, varscan2
- LRP1B | c.9180C>T p.I3060= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs774022861, COSV101256803, COSV67192452; called by muse, mutect2, varscan2
- LRRIQ4 | c.744C>T p.S248= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV61620006; called by muse, mutect2, varscan2
- LVRN | c.516C>T p.G172= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1302993990, COSV100773601; called by muse, mutect2
- MAGEL2 | c.2343G>A p.E781= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100045805, COSV100046119; called by muse, mutect2, varscan2
- MC3R | c.549G>A p.S183= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as rs1411606418, COSV54763790; called by muse, mutect2, varscan2
- MCM8 | c.309C>T p.F103= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99177596; called by muse, mutect2, varscan2
- MUC16 | c.22590G>A p.R7530= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV67462939; called by muse, mutect2, varscan2
- MYH1 | c.4428G>A p.K1476= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV99876572; called by muse, mutect2, varscan2
- MYH11 | c.5703G>A p.R1901= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as COSV100259723; called by muse, mutect2, varscan2
- MYH8 | c.3888G>A p.E1296= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV101238574; called by muse, mutect2, varscan2
- MYO7B | c.5982G>A p.K1994= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100264868; called by muse, mutect2, varscan2
- NCOR2 | c.1617G>A p.E539= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100657715; called by muse, mutect2, varscan2
- NINL | c.3618A>G p.E1206= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs1169926613, COSV99625872; called by muse, mutect2, varscan2
- NPHP4 | c.2994C>T p.P998= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100977082; called by muse, mutect2, varscan2
- OR10K1 | c.144C>T p.T48= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs536094744, COSV56874270, COSV99193822; called by muse, mutect2, varscan2
- OR1D5 | c.279C>T p.S93= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1161633376, COSV101643439; called by mutect2, varscan2
- OR4N2 | c.381C>T p.C127= | Silent (SNP) | VAF 76/291 reads (26%) | catalogued as rs1352772723, COSV100269845; called by muse, mutect2, varscan2
- OVGP1 | c.783C>T p.P261= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV100868237; called by muse, mutect2, varscan2
- PALMD | c.1131G>A p.G377= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV54166697; called by muse, mutect2, varscan2
- PAPOLA | c.1362T>G p.V454= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99354486; called by muse, mutect2
- PARS2 | c.1230G>A p.L410= | Silent (SNP) | VAF 57/154 reads (37%) | catalogued as COSV100988319; called by muse, mutect2, varscan2
- PCDHA4 | c.675C>T p.T225= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as COSV100793629; called by muse, mutect2, varscan2
- PCDHB12 | c.1377C>T p.F459= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as rs782545132, COSV53399170; called by muse, mutect2, varscan2
- PCDHB13 | c.510C>T p.N170= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV99507603; called by muse, mutect2, varscan2
- PCDHB5 | c.1374C>T p.F458= | Silent (SNP) | VAF 80/227 reads (35%) | catalogued as rs376440692; called by muse, mutect2, varscan2
- PCDHGA9 | c.981G>A p.L327= | Silent (SNP) | VAF 63/139 reads (45%) | catalogued as COSV99543321; called by muse, mutect2, varscan2
- PGD | c.1122A>T p.G374= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as COSV99581603; called by muse, mutect2, varscan2
- PGM5 | c.1701C>T p.T567= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1373686694, COSV101124010; called by muse, mutect2, varscan2
- PICALM | c.228C>T p.F76= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100708060; called by muse, mutect2, varscan2
- PIK3R6 | c.753G>A p.L251= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100266742; called by muse, mutect2, varscan2
- PLAAT5 | c.468C>T p.V156= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as COSV100080581; called by muse, mutect2, varscan2
- PLEK | c.774G>A p.R258= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as COSV52250803; called by muse, mutect2, varscan2
- PLK1 | c.1527C>T p.P509= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1414921701, COSV99892045; called by muse, mutect2, varscan2
- PLXNA4 | c.2937G>A p.L979= | Silent (SNP) | VAF 112/261 reads (43%) | catalogued as rs868399386, COSV100326065; called by muse, mutect2, varscan2
- PRSS1 | c.243G>A p.L81= | Silent (SNP) | VAF 67/141 reads (48%) | catalogued as rs142476093; called by muse, mutect2, varscan2
- PTOV1 | c.1047C>T p.G349= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV55588588; called by muse, mutect2, varscan2
- PTPN7 | c.861C>T p.I287= (on ENST00000495688; = p.I326= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs200658575, COSV58312678; called by muse, mutect2, varscan2
- PTPRD | c.4095C>T p.D1365= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1487661697, COSV100645980; called by muse, mutect2, varscan2
- PTX4 | c.870C>T p.F290= (on ENST00000447419 / NM_001328608.2; = p.F285= on NM_001013658.1) | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as rs547860335, COSV53516488; called by muse, mutect2, varscan2
- RASSF9 | c.1086G>A p.K362= | Silent (SNP) | VAF 81/205 reads (40%) | catalogued as rs1211257924, COSV100771363; called by muse, mutect2, varscan2
- RBM47 | c.306C>T p.L102= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV99921264; called by muse, mutect2, varscan2
- RELB | c.1476C>T p.D492= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs374372014; called by muse, mutect2, varscan2
- RHBDF1 | c.423C>T p.P141= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV99244977; called by muse, mutect2, varscan2
- RTP5 | c.1632C>T p.F544= | Silent (SNP) | VAF 58/144 reads (40%) | catalogued as COSV100574781; called by muse, mutect2, varscan2
- RYR2 | c.3897C>T p.I1299= | Silent (SNP) | VAF 90/250 reads (36%) | catalogued as COSV100772083; called by muse, mutect2, varscan2
- SCGN | c.735C>T p.F245= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as COSV100618813; called by muse, mutect2, varscan2
- SDK1 | c.2430G>A p.L810= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV101269656; called by muse, mutect2, varscan2
- SETBP1 | c.1233G>A p.L411= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99953195; called by muse, mutect2, varscan2
- SLC13A5 | c.942C>T p.F314= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as rs546617630, COSV99546074; called by muse, mutect2, varscan2
- SLC17A3 | c.150C>T p.F50= | Silent (SNP) | VAF 46/89 reads (52%) | catalogued as COSV100399350; called by muse, mutect2, varscan2
- SLC24A2 | c.57G>A p.E19= | Silent (SNP) | VAF 66/176 reads (38%) | catalogued as rs1322576801, COSV99647118; called by muse, mutect2, varscan2
- SLC52A3 | c.672C>T p.F224= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV54076763; called by muse, mutect2, varscan2
- SLC5A12 | c.1116C>T p.L372= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV99745306; called by muse, mutect2, varscan2
- SMARCC2 | c.1092G>A p.K364= | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as COSV99911718; called by muse, mutect2, varscan2
- SOBP | c.933C>G p.A311= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs1244817666, COSV100433322, COSV57998322; called by muse, mutect2, varscan2
- SPA17 | c.309C>T p.I103= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV99907140; called by muse, mutect2, varscan2
- SPOCK3 | c.1014C>T p.I338= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as COSV62728595; called by muse, mutect2, varscan2
- STK32A | c.1140G>A p.L380= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1467406462, COSV101204891; called by muse, mutect2, varscan2
- SZT2 | c.5796A>T p.A1932= (on ENST00000634258 / NM_001365999.1; = p.A1875= on NM_015284.4) | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100987536; called by muse, mutect2, varscan2
- SZT2 | c.7935C>T p.P2645= (on ENST00000634258 / NM_001365999.1; = p.P2588= on NM_015284.4) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1384360032, COSV100987538, COSV100987697; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAF1C | c.2589G>A p.K863= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs773455339, COSV58989645; called by muse, mutect2, varscan2
- TAF1L | c.4176C>T p.S1392= | Silent (SNP) | VAF 85/236 reads (36%) | catalogued as rs1460241724, COSV99645174; called by muse, mutect2, varscan2
- TAF5L | c.475C>T p.L159= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as COSV99273510; called by muse, mutect2, varscan2
- TCAIM | c.414C>T p.I138= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV61239780, COSV61242869; called by muse, mutect2, varscan2
- TET3 | c.1860C>T p.L620= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV59880595; called by muse, mutect2, varscan2
- TFDP3 | c.565C>T p.L189= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs760417214, COSV100033478; called by muse, mutect2, varscan2
- THAP10 | c.483T>G p.S161= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99997853; called by muse, mutect2, varscan2
- TIA1 | c.318C>T p.F106= (on ENST00000433529 / NM_001351511.1; = p.F95= on NM_022037.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs770120862, COSV99248883; called by muse, mutect2, varscan2
- TMEM202 | c.765G>A p.E255= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100499226; called by muse, mutect2, varscan2
- TMPO | c.1621C>T p.L541= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs758516834, COSV99702152; called by muse, mutect2, varscan2
- TMPRSS11E | c.576C>T p.I192= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as rs1353476169, COSV59517810; called by muse, mutect2, varscan2
- TRIM22 | c.702C>T p.I234= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV101181436; called by muse, varscan2
- TRIM54 | c.870C>T p.V290= (on ENST00000380075 / NM_187841.3; = p.V332= on NM_032546.4) | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs780684328, COSV99274462; called by muse, mutect2, varscan2
- TUBGCP2 | c.2040C>T p.F680= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV99428122; called by muse, mutect2, varscan2
- UBXN8 | c.588C>A p.L196= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99668031; called by muse, mutect2
- UCN3 | c.207G>A p.S69= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs781880308, COSV100991727; called by muse, mutect2, varscan2
- USH2A | c.5613T>G p.G1871= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100239512; called by muse, mutect2, varscan2
- USP26 | c.1710C>T p.F570= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as COSV100896714, COSV100896797; called by muse, mutect2, varscan2
- VDAC3 | c.507C>T p.F169= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs767701788, COSV50081274; called by muse, mutect2, varscan2
- VN1R2 | c.627T>C p.I209= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100448096; called by muse, mutect2, varscan2
- VPS37A | c.852C>T p.L284= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs1174262580, COSV100249015; called by muse, mutect2, varscan2
- WDR86 | c.471G>A p.A157= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs369396478; called by muse, mutect2
- WNT3 | c.912C>T p.S304= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV99843370; called by muse, mutect2, varscan2
- WNT3A | c.135C>T p.I45= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV99469921; called by muse, mutect2, varscan2
- XPO5 | c.273G>A p.K91= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99541237; called by muse, mutect2, varscan2
- ZBTB49 | c.66C>G p.G22= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as COSV100552537, COSV61924596; called by muse, mutect2, varscan2
- ZBTB49 | c.67C>T p.L23= | Silent (SNP) | VAF 53/149 reads (36%) | catalogued as COSV100552539; called by muse, mutect2, varscan2
- ZBTB5 | c.384C>T p.P128= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as rs1389236100, COSV100312882; called by muse, mutect2, varscan2
- ZNF229 | c.1026C>T p.A342= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as rs1423235097, COSV99350703; called by muse, mutect2, varscan2
- ZNF280C | c.747G>A p.L249= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100921258; called by muse, mutect2, varscan2
- ZNF669 | c.945C>T p.F315= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100594305; called by muse, mutect2, varscan2
- ZNF71 | c.687C>T p.L229= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV60150231; called by muse, mutect2, varscan2
- AIPL1 | c.-1C>T | 5'UTR (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100006161; called by muse, mutect2, varscan2
- AIPL1 | c.-2C>T | 5'UTR (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100006162; called by muse, mutect2, varscan2
- COL5A1 | c.654+7295C>T | Intron (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100880311; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446115 G>A | 3'Flank (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2
- FABP5P3 | chr7:152446117 A>T | 3'Flank (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2
- FAM183BP | n.1193G>A | RNA (SNP) | VAF 60/158 reads (38%) | called by muse, mutect2, varscan2
- FRMPD2B | n.901C>T | RNA (SNP) | VAF 60/173 reads (35%) | called by muse, mutect2, varscan2
- IFRD2 | chr3:50292627 C>T | 5'Flank (SNP) | VAF 21/40 reads (53%) | catalogued as COSV100269725, COSV57113280; called by muse, mutect2, varscan2
- KCNU1 | c.2010-16897G>A | Intron (SNP) | VAF 15/19 reads (79%) | catalogued as rs1335213649; called by muse, mutect2, varscan2
- MAGI1 | c.2417-3539G>A | Intron (SNP) | VAF 25/50 reads (50%) | catalogued as rs200026736; called by muse, mutect2, varscan2
- MICAL3 | c.2605+192G>A | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99262525; called by muse, mutect2, varscan2
- MIR411 | n.90C>T | RNA (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- NEBL | c.164+46264G>A | Intron (SNP) | VAF 33/81 reads (41%) | catalogued as rs1305382022, COSV101008815; called by muse, mutect2, varscan2
- OR2U1P | n.116G>A | RNA (SNP) | VAF 66/172 reads (38%) | catalogued as rs867049767; called by muse, mutect2, varscan2
- PRRX1 | c.599+3885C>T | Intron (SNP) | VAF 73/194 reads (38%) | catalogued as rs879138324, COSV99510088; called by muse, mutect2, varscan2
- RFX7 | c.-63C>T | 5'UTR (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100429146; called by muse, mutect2, varscan2
- SLC6A15 | c.756+93C>T | Intron (SNP) | VAF 34/79 reads (43%) | catalogued as COSV99880813, COSV99881313; called by muse, mutect2, varscan2
- SZT2 | c.*506C>G | 3'UTR (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100981322; called by muse, mutect2
- SZT2 | c.*508C>T | 3'UTR (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100981323; called by muse, mutect2
- TNK2 | c.-18-6793C>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs760272195, COSV100361556; called by muse, varscan2
- TTN | c.10360+4673C>T | Intron (SNP) | VAF 57/130 reads (44%) | catalogued as COSV100623176; called by muse, mutect2, varscan2
